Somatic mutation profile of tumor specimen TCGA-J4-AAU2-01A (aliquot TCGA-J4-AAU2-01A-11D-A41K-08) from TCGA case TCGA-J4-AAU2, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.3 years (21,656 days).
Specimen TCGA-J4-AAU2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbaefc38-4cac-4d09-b8c5-9b3265872b86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-AAU2-10A (Blood Derived Normal), aliquot TCGA-J4-AAU2-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf574977-f78f-4574-b027-050936d88a93

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 17, Silent 4, Frame Shift Ins 2, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.6149T>G p.I2050S | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as CM990282, COSV100971577; called by muse, mutect2, varscan2
- COL5A1 | c.2725C>T p.R909W | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1257715072, COSV100880665; called by muse, mutect2, varscan2
- DNHD1 | c.14155A>T p.K4719* | Nonsense Mutation (SNP) | VAF 33/91 reads (36%) | catalogued as COSV99601110; called by muse, mutect2, varscan2
- FGF16 | c.443C>A p.A148D | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV101466330; called by muse, mutect2, varscan2
- KMT2C | c.5929del p.Q1977Nfs*13 | Frame Shift Del (DEL) | VAF 78/207 reads (38%) | catalogued as COSV51454142, COSV99030560; called by mutect2, pindel, varscan2
- KRT81 | c.665A>T p.K222M | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100577033; called by muse, mutect2
- LILRB1 | c.1211G>A p.R404H (on ENST00000427581; = p.R368H on NM_006669.6) | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs376255659, COSV61116430, COSV61117673; called by muse, varscan2
- MYH3 | c.4526A>C p.E1509A | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99878023, COSV99879029; called by muse, mutect2, varscan2
- OR6N2 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.798); catalogued as COSV100210549; called by muse, mutect2
- PARP4 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101132133; called by muse, mutect2, varscan2
- PLAGL2 | c.1232A>G p.N411S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs1258727083, COSV99867638; called by muse, mutect2, varscan2
- PTPN3 | c.2231C>T p.T744M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750440450, COSV52706432; called by muse, mutect2, varscan2
- PTPN5 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.469); catalogued as rs200135035, COSV100660004; called by mutect2, varscan2
- UFL1 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.815); catalogued as COSV100990153; called by muse, mutect2, varscan2
- USP28 | c.435G>A p.W145* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV99137064; called by muse, mutect2, varscan2
- ZNF112 | c.1036C>G p.L346V (on ENST00000337401 / NM_001083335.2; = p.L340V on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100496377; called by muse, mutect2
- ZNF544 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs565406296, COSV99517303; called by muse, mutect2, varscan2
- ARID5B | c.2729_2732dup p.K912Sfs*56 | Frame Shift Ins (INS) | VAF 7/59 reads (12%) | called by mutect2, pindel
- CACNA1B | c.675G>T p.Q225H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2
- HNRNPL | c.729T>G p.S243R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- KMT2D | c.871dup p.C291Lfs*2 | Frame Shift Ins (INS) | VAF 31/86 reads (36%) | called by mutect2, pindel, varscan2
- TMEM236 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 24/401 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.263); called by muse, mutect2
- EVC | c.243C>A p.S81= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV99382704; called by muse, mutect2, varscan2
- F5 | c.5826T>A p.G1942= | Silent (SNP) | VAF 6/128 reads (5%) | catalogued as COSV100889276; called by muse, mutect2
- NSD3 | c.1905C>T p.R635= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as rs774588087, COSV100388995; called by muse, mutect2, varscan2
- TRAPPC11 | c.576T>C p.F192= | Silent (SNP) | VAF 5/85 reads (6%) | catalogued as COSV100592073; called by muse, mutect2
